TARGET case TARGET-40-NAAHBV — Osteosarcoma (TARGET-OS)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Osseous and Chondromatous Neoplasms; Primary site: Bones, joints and articular cartilage of other and unspecified sites. Index date (day 0 for every day count below): diagnosis.
https://portal.gdc.cancer.gov/cases/37fd908c-03c6-578e-a2d2-5463c0834b39

Demographics
Sex at birth: male; Age at index: 16 years; Vital status: Alive.

Diagnoses (1)
1. Osteosarcoma, NOS: ICD-O-3 morphology code: 9180/3; ICD-10 code: C41.9; Classification of tumor: primary; Age at diagnosis: 16.6 years (6,066 days); Year of diagnosis: 2001; Metastasis at diagnosis: No Metastasis; Days to last follow up: 1,260 days (3.4 years).
   Pathology details: Necrosis percent: 60.
   Treatment given: Protocol identifier: BCM.

Follow-up (2 entries)
- Days to follow up: 213 days; Days to first event: 213 days; First event: Second Malignant Neoplasm.
- Days to follow up: 1,260 days (3.4 years); Year of follow up: 2004.

Biospecimens (1 sample)
- Sample TARGET-40-NAAHBV-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.

Additional fields from the TARGET clinical supplement workbook TARGET_OS_ClinicalData_Validation_20230329.xlsx (sheet Clinical Data):
- Overall Survival Time in Days: 1260
- Protocol: BCM
- Disease at diagnosis: Non-metastatic
